Gene-level copy-number profile of tumor specimen TCGA-BP-4781-01A from TCGA case TCGA-BP-4781, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 78.6 years (28,701 days).
Specimen TCGA-BP-4781-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-KIRC.e0738da6-a005-4886-9786-f5bbc0ad3ee6.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-BP-4781-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2.
https://portal.gdc.cancer.gov/files/5b070ceb-f80c-43c5-a6c3-e657915d96a6

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 1,203; copy number 2: 5,654; copy number 3: 8,395; copy number 4: 33,417; copy number 5: 4,065; copy number 6: 4,075; copy number 7: 201; copy number 8: 1,854; copy number 9: 956.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 956 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:8,938,787–64,266,931, 956 genes, copy number 9 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,203. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
